Somatic mutation profile of tumor specimen MMRF_2215_1_BM_CD138pos (aliquot MMRF_2215_1_BM_CD138pos_T1_KHS5U_K14043) from MMRF case MMRF_2215, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.9 years (26,246 days).
Specimen MMRF_2215_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 455df994-3b41-41a5-8220-bba69395d0a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2215_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2215_1_PB_Whole_C1_KHS5U_K14042; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e51a6523-8631-45b1-9785-c5d374dfe1cc

The open-access MAF lists 112 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 29, Silent 13, Intron 12, RNA 4, 5'UTR 3, Splice Site 1, 5'Flank 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADI1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs754050453, COSV59376178; called by muse, mutect2, varscan2
- AMBRA1 | c.3635G>A p.R1212Q (on ENST00000458649 / NM_001367468.1; = p.R1122Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as rs149624973; called by muse, mutect2, varscan2
- CDC42BPA | c.3863G>A p.R1288H (on ENST00000334218 / NM_001366019.2; = p.R1275H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.177); catalogued as rs752231516, COSV62005573; called by muse, mutect2, varscan2
- CFAP300 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs769338189; called by muse, mutect2, varscan2
- COL18A1 | c.3697G>A p.G1233R (on ENST00000359759 / NM_130444.3; = p.G998R on NM_030582.4) | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372658384; called by muse, mutect2, varscan2
- EML5 | c.5741A>C p.K1914T (on ENST00000380664; = p.K1922T on NM_183387.3) | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255966718; called by muse, mutect2, varscan2
- FANK1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs781154409, COSV64161130; called by muse, mutect2
- FLG | c.9541C>T p.R3181C | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs555274375, COSV64243323; called by muse, mutect2, varscan2
- FOXO1 | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755802918, COSV65428968; called by muse, mutect2, varscan2
- GLIS1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs376288261; called by muse, mutect2
- HTR3A | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs144629647; called by muse, mutect2
- IGHJ6 | c.43A>T p.T15S | Missense Mutation (SNP) | VAF 46/92 reads (50%) | PolyPhen benign (0); catalogued as rs376921777; called by muse, varscan2
- IGHV3-21 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as rs375657552; called by muse, mutect2, varscan2
- IGHV3-21 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs547151566; called by muse, varscan2
- IGHV3-21 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 106/222 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs372488167; called by muse, varscan2
- IGHV3-23 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs782809838; called by muse, mutect2, varscan2
- IGLV3-1 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs180853064; called by muse, mutect2, varscan2
- INHBE | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV99875285; called by muse, mutect2, varscan2
- KCTD8 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100759976; called by muse, mutect2, varscan2
- LRP12 | c.1732C>A p.L578M | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs745813370, COSV52627980, COSV99407877; called by muse, mutect2, varscan2
- NTSR2 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs149468069; called by muse, mutect2
- PARD6G | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); catalogued as rs758328356, COSV100783399; called by muse, mutect2, varscan2
- PIK3C2B | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1362684590, COSV65812291; called by muse, mutect2
- PLEKHG4B | c.3799C>T p.R1267C (on ENST00000283426; = p.R1623C on NM_052909.5) | Missense Mutation (SNP) | VAF 134/170 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs765464969; called by muse, mutect2, varscan2
- PLPP7 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.313); catalogued as rs780826946; called by muse, mutect2
- SCAF4 | c.938C>G p.P313R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV54589031; called by mutect2, varscan2
- SLC37A2 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273370878; called by muse, mutect2, varscan2
- ASIC2 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BBS5 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CATSPER3 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.041); called by muse, mutect2
- COQ2 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUOXA2 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DXO | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DYTN | c.1598A>G p.K533R | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EYS | c.6077_6078+6del p.X2026_splice | Splice Site (DEL) | VAF 56/159 reads (35%) | called by mutect2, pindel, varscan2
- FAT4 | c.9938C>A p.A3313D | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GMIP | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRK2 | c.1434C>G p.N478K | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV2-70D | c.234A>C p.K78N | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, varscan2
- IGKV1-5 | c.335A>T p.Q112L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MASTL | c.2154_2155del p.P719Ifs*15 (on ENST00000375940 / NM_001372029.1; = p.P718Ifs*15 on NM_032844.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/168 reads (36%) | called by mutect2, pindel, varscan2
- NID1 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NOP14 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.197); called by muse, mutect2
- PRDM1 | c.1859A>G p.K620R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRN | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SELENON | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TBC1D20 | c.779A>C p.Y260S | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- USP24 | c.7210G>T p.A2404S | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF599 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CD163 | c.2088G>A p.S696= | Silent (SNP) | VAF 93/210 reads (44%) | catalogued as rs536972277, COSV63129352, COSV63130268; called by muse, mutect2, varscan2
- CFAP45 | c.1230G>A p.A410= | Silent (SNP) | VAF 40/438 reads (9%) | catalogued as rs759821163, COSV63648460, COSV63649435; called by muse, mutect2
- EBF3 | c.969C>T p.V323= (on ENST00000355311 / NM_001375392.1; = p.V314= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 112/213 reads (53%) | catalogued as rs1403933688; called by muse, mutect2, varscan2
- FBXL18 | c.957C>T p.F319= | Silent (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
- FXR1 | c.1071T>C p.Y357= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.75G>A p.E25= | Silent (SNP) | VAF 46/166 reads (28%) | called by muse, varscan2
- IGHV2-70D | c.52T>C p.L18= | Silent (SNP) | VAF 55/163 reads (34%) | called by muse, varscan2
- IGHV3-21 | c.204A>G p.S68= | Silent (SNP) | VAF 136/202 reads (67%) | catalogued as rs372507616; called by muse, varscan2
- IRF2BP2 | c.729C>T p.S243= | Silent (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- SLC29A3 | c.1290C>T p.S430= | Silent (SNP) | VAF 141/283 reads (50%) | called by muse, mutect2, varscan2
- TBC1D2 | c.1014C>T p.A338= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs376244283; called by muse, mutect2, varscan2
- TLK1 | c.1260A>G p.E420= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs41268695; called by muse, mutect2, varscan2
- TM4SF5 | c.363C>T p.N121= | Silent (SNP) | VAF 23/230 reads (10%) | catalogued as rs756181828, COSV54496132; called by muse, mutect2
- AC006971.1 | n.518A>T | RNA (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- AL359555.4 | n.423C>T | RNA (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- ALX4 | c.*2229G>C | 3'UTR (SNP) | VAF 15/346 reads (4%) | called by muse, mutect2
- ANO7 | c.472-69T>G | Intron (SNP) | VAF 20/193 reads (10%) | called by muse, mutect2, varscan2
- AP1G2 | c.*101G>A | 3'UTR (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*3016G>A | 3'UTR (SNP) | VAF 11/134 reads (8%) | catalogued as rs901842701; called by muse, mutect2
- CCSER1 | c.2011-34978A>C | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- CFAP300 | c.*438T>C | 3'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- CLDN11 | c.*853C>T | 3'UTR (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- COL22A1 | c.*94G>C | 3'UTR (SNP) | VAF 113/331 reads (34%) | called by muse, mutect2, varscan2
- CRKL | c.*3762G>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | catalogued as rs1017558135, COSV100574182; called by muse, mutect2, varscan2
- DTX3L | c.*3180A>T | 3'UTR (SNP) | VAF 28/86 reads (33%) | catalogued as rs533274568, COSV56144068; called by muse, mutect2, varscan2
- DUSP2 | c.*68C>G | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- EEPD1 | c.*1641C>T | 3'UTR (SNP) | VAF 50/113 reads (44%) | catalogued as rs768063452; called by muse, mutect2, varscan2
- EFNA5 | c.*940G>C | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- EIF2S2 | c.-113C>G | 5'UTR (SNP) | VAF 79/176 reads (45%) | called by muse, mutect2, varscan2
- EIF4H | c.313-13C>A | Intron (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- EYS | c.1766+2881T>A | Intron (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- FAM53B | c.*2428G>T | 3'UTR (SNP) | VAF 53/92 reads (58%) | called by muse, mutect2, varscan2
- FBXL16 | c.*856C>T | 3'UTR (SNP) | VAF 48/84 reads (57%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.183C>T | RNA (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- GABRB2 | c.*1317A>G | 3'UTR (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- GABRQ | c.*2949C>T | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- HMGCR | c.*1079A>G | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- IDS | c.-150_-138del | 5'UTR (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- KRBOX1 | c.-47+933A>T | Intron (SNP) | VAF 72/113 reads (64%) | called by muse, mutect2, varscan2
- KRTAP4-7 | c.*253G>T | 3'UTR (SNP) | VAF 7/111 reads (6%) | catalogued as COSV101195192; called by muse, mutect2
- LINC01749 | n.349C>T | RNA (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- NPC2 | chr14:74476518 C>T | 3'Flank (SNP) | VAF 52/143 reads (36%) | called by muse, mutect2, varscan2
- OSGEP | c.793+45A>G | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- PDE10A | c.*74T>G | 3'UTR (SNP) | VAF 12/22 reads (55%) | catalogued as rs551090151, COSV63095954; called by muse, varscan2
- PELI1 | c.*1939T>A | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- PGK2 | c.*64C>T | 3'UTR (SNP) | VAF 11/75 reads (15%) | catalogued as rs986439752; called by muse, mutect2, varscan2
- PHYH | chr10:13302004 T>G | 5'Flank (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- PLCXD3 | c.-35T>C | 5'UTR (SNP) | VAF 16/224 reads (7%) | catalogued as COSV60621745; called by muse, mutect2
- PTK2B | c.2549-723C>A | Intron (SNP) | VAF 25/59 reads (42%) | catalogued as rs1475227729; called by muse, mutect2, varscan2
- RGS3 | c.1915-33del | Intron (DEL) | VAF 47/200 reads (24%) | called by mutect2, pindel, varscan2
- RGS7BP | c.*1762A>G | 3'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- SARS1 | c.1258-299G>A | Intron (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- SELENOI | c.*3833G>A | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- SETD3 | c.849+230A>G | Intron (SNP) | VAF 17/161 reads (11%) | catalogued as rs964749576; called by muse, mutect2, varscan2
- SIAE | c.*598C>T | 3'UTR (SNP) | VAF 81/134 reads (60%) | catalogued as rs761915808; called by muse, mutect2, varscan2
- SSTR1 | c.*1728T>A | 3'UTR (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- STT3B | c.*1523G>A | 3'UTR (SNP) | VAF 33/102 reads (32%) | catalogued as rs1270920817; called by muse, mutect2, varscan2
- TMEM184C | c.*1382C>A | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- TRAF3 | c.820-2067G>A | Intron (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- WDR37 | c.138+2141C>T | Intron (SNP) | VAF 50/112 reads (45%) | called by muse, varscan2
- YIPF4 | c.*111G>T | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- ZBBX | c.*186T>C | 3'UTR (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- ZNF365 | c.*845G>A | 3'UTR (SNP) | VAF 77/132 reads (58%) | catalogued as rs987528837; called by muse, mutect2, varscan2
